CCDI case PBBUAW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/c4916166-525b-49f0-a7af-f07b1f54c6a8

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: External ear; Age at diagnosis: 4.9 years (1,772 days).

Biospecimens (3 samples)
- Sample 0DH5UB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5V4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5VT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
